Somatic mutation profile of tumor specimen MP2PRT-PAUMHP-TMP1-A (aliquot MP2PRT-PAUMHP-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUMHP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,375 days).
Specimen MP2PRT-PAUMHP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12c75e9f-4c3e-4648-bcf1-271191dd79f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMHP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMHP-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac51f004-4753-4b4a-a128-84357957d6f0

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 110/312 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASIC2 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99861098; called by muse, mutect2, varscan2
- CHEK1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs537858020; called by muse, mutect2, varscan2
- CPNE7 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs936806127, COSV52013541; called by muse, mutect2, varscan2
- FSIP2 | c.17759C>T p.S5920F | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1300520924, COSV100555051; called by muse, mutect2, varscan2
- GPR158 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 172/471 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350723305, COSV66274209; called by muse, mutect2, varscan2
- HEPH | c.2182C>T p.R728C (on ENST00000343002; = p.R461C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/567 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.462); catalogued as rs755587522, COSV57958673; called by muse, mutect2
- KRTAP4-6 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 238/845 reads (28%) | SIFT deleterious (0.03); catalogued as rs780303828; called by muse, mutect2, varscan2
- LRP1B | c.10060G>A p.E3354K | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV101251928; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 123/446 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORCS3 | c.3358G>A p.A1120T | Missense Mutation (SNP) | VAF 115/572 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV63809373; called by muse, mutect2, varscan2
- ZNF729 | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV62605484; called by muse, mutect2, varscan2
- AMER3 | c.1204_1205insGGC p.A402delinsGP | In Frame Ins (INS) | VAF 127/374 reads (34%) | called by mutect2, pindel, varscan2
- BCL11B | c.2008C>T p.P670S (on ENST00000357195 / NM_001282237.2; = p.P599S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/410 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREM | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 111/440 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- FAT4 | c.9608C>T p.P3203L | Missense Mutation (SNP) | VAF 137/468 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HMX1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 153/498 reads (31%) | PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- WDR19 | c.2978T>C p.M993T | Missense Mutation (SNP) | VAF 110/332 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NR2E3 | c.132G>A p.S44= | Silent (SNP) | VAF 115/271 reads (42%) | catalogued as rs759064828, COSV58907728; called by muse, mutect2, varscan2
- OR5K4 | c.102C>T p.I34= | Silent (SNP) | VAF 134/330 reads (41%) | catalogued as rs1408053978; called by muse, mutect2, varscan2
- OR6C76 | c.279T>A p.A93= | Silent (SNP) | VAF 100/230 reads (43%) | called by muse, mutect2, varscan2
- OVCH1 | c.1215T>A p.L405= | Silent (SNP) | VAF 128/286 reads (45%) | called by muse, mutect2, varscan2
- WWC1 | c.1605C>T p.S535= | Silent (SNP) | VAF 233/487 reads (48%) | called by muse, mutect2, varscan2
- TMEM78 | n.164A>G | RNA (SNP) | VAF 192/386 reads (50%) | called by muse, mutect2, varscan2
